Somatic mutation profile of tumor specimen MMRF_2740_1_BM_CD138pos (aliquot MMRF_2740_1_BM_CD138pos_T1_KHS5U_L14895) from MMRF case MMRF_2740, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow.
Specimen MMRF_2740_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de7d9e7f-f1d5-4bdd-99ea-40f8eb201db4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2740_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2740_1_PB_WBC_C3_KHS5U_L14896; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32d75ff7-4def-42e8-943f-c7ff6bbea7b7

The open-access MAF lists 106 somatic variants for this specimen: 52 protein-altering or splice-affecting, 12 silent, 42 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, 3'UTR 16, Intron 14, Silent 12, 5'Flank 4, RNA 4, 5'UTR 3, Frame Shift Del 2, Nonsense Mutation 2, 3'Flank 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CELSR1 | c.3937G>A p.E1313K | Missense Mutation (SNP) | VAF 24/220 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.362); catalogued as rs763382137, COSV53100956; called by muse, mutect2, varscan2
- CPNE3 | c.983C>T p.S328F | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV99547331; called by muse, mutect2
- CYP2B6 | c.1301G>A p.R434Q | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs764288403, COSV100137551, COSV57843577; called by muse, mutect2, varscan2
- DMD | c.9497A>G p.N3166S | Missense Mutation (SNP) | VAF 72/153 reads (47%) | SIFT tolerated (0.6); PolyPhen benign (0.044); catalogued as rs911738713; called by muse, mutect2, varscan2
- EED | c.63G>C p.Q21H | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.948); catalogued as rs1186239339; called by muse, mutect2, varscan2
- EEF1A1 | c.775A>G p.I259V | Missense Mutation (SNP) | VAF 80/157 reads (51%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.062); catalogued as rs772165099, COSV58549759; called by muse, mutect2, varscan2
- FBXW5 | c.1082C>T p.S361F | Missense Mutation (SNP) | VAF 48/161 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as rs749598387; called by muse, mutect2, varscan2
- GTPBP3 | c.422G>A p.G141D | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769418711; called by muse, mutect2, varscan2
- HCAR2 | c.373A>G p.R125G | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371493470; called by muse, mutect2, varscan2
- INSC | c.802G>C p.E268Q | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as COSV65411912; called by muse, mutect2, varscan2
- JPH1 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 29/229 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.926); catalogued as COSV60611180; called by muse, mutect2, varscan2
- KMT2D | c.16441T>C p.C5481R | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD114941; called by muse, mutect2, varscan2
- OPN3 | c.427G>A p.V143M | Missense Mutation (SNP) | VAF 33/185 reads (18%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.957); catalogued as rs745934994; called by muse, mutect2, varscan2
- OR5T3 | c.602G>A p.C201Y | Missense Mutation (SNP) | VAF 12/294 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as rs1282157786; called by muse, mutect2
- PAK5 | c.1462C>T p.R488* | Nonsense Mutation (SNP) | VAF 154/308 reads (50%) | catalogued as rs771840400, COSV62022713, COSV62038071; called by muse, mutect2, varscan2
- PCDH19 | c.3341G>C p.R1114P (on ENST00000373034 / NM_001184880.2; = p.R1066P on NM_020766.3) | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.519); catalogued as rs770137596; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PHIP | c.4775C>T p.S1592F | Missense Mutation (SNP) | VAF 109/300 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.424); catalogued as rs1329890435; called by muse, mutect2, varscan2
- SLC23A3 | c.1721C>G p.P574R (on ENST00000409878 / NM_001144889.2; = p.P457R on NM_144712.5) | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.07); catalogued as COSV55407590; called by muse, mutect2, varscan2
- SLX4 | c.1192C>T p.R398W | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138799572; ClinVar: uncertain significance; called by muse, mutect2
- TPRG1 | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 89/134 reads (66%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs370291238; called by muse, mutect2, varscan2
- ZFP57 | c.1426C>T p.R476W | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs190525528; called by muse, mutect2, varscan2
- ANKRD9 | c.802del p.Q268Sfs*56 | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | called by mutect2, pindel, varscan2
- AR | c.2485G>A p.D829N | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ARVCF | c.170G>A p.G57E | Missense Mutation (SNP) | VAF 52/107 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- ATP2C1 | c.842T>C p.M281T | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- BAIAP2L2 | c.517C>T p.Q173* | Nonsense Mutation (SNP) | VAF 39/96 reads (41%) | called by muse, mutect2, varscan2
- C20orf194 | c.3273G>C p.R1091S | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CHD4 | c.5294A>C p.E1765A (on ENST00000357008 / NM_001363606.2; = p.E1776A on NM_001273.5) | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- GABBR1 | c.2223T>A p.F741L | Missense Mutation (SNP) | VAF 60/123 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- GABRA3 | c.1372A>T p.I458F | Missense Mutation (SNP) | VAF 52/157 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- H2AC1 | c.152A>G p.Y51C | Missense Mutation (SNP) | VAF 57/195 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- IGHV2-70D | c.336del p.T113Rfs*? | Frame Shift Del (DEL) | VAF 26/82 reads (32%) | called by pindel, varscan2
- IGHV2-70D | c.265A>G p.T89A | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.108); called by muse, varscan2
- IGHV2-70D | c.229G>T p.D77Y | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.646); called by muse, varscan2
- IGHV3-33 | c.335T>G p.V112G | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- IGKJ2 | c.4_11delinsAC p.C2_F4delinsY | In Frame Del (DEL) | VAF 63/135 reads (47%) | called by pindel, varscan2*
- KDM6A | c.3767A>T p.Y1256F | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LARS1 | c.1970A>C p.Q657P (on ENST00000394434 / NM_020117.11; = p.Q630P on NM_016460.3) | Missense Mutation (SNP) | VAF 20/288 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.119); called by muse, mutect2
- MCOLN2 | c.261C>G p.N87K | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYBPHL | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- NCKAP1L | c.3236C>T p.T1079I | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT tolerated (0.75); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NUP214 | c.2893+5A>C | Splice Region (SNP) | VAF 40/149 reads (27%) | called by muse, mutect2, varscan2
- PCLO | c.8651C>T p.T2884I | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PDZRN4 | c.2802G>C p.E934D (on ENST00000402685 / NM_001164595.2; = p.E676D on NM_013377.4) | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PLCH1 | c.1733C>T p.T578I (on ENST00000340059 / NM_001130960.2; = p.T590I on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- RGS6 | c.464A>C p.N155T | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- RRS1 | c.917T>A p.M306K | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SBK1 | c.577G>T p.A193S | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.07); called by muse, varscan2
- SLC33A1 | c.929T>C p.V310A | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2
- SRRM4 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- TLCD3B | c.236A>G p.Q79R | Missense Mutation (SNP) | VAF 32/256 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- USP16 | c.923T>G p.L308W | Missense Mutation (SNP) | VAF 86/179 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C19orf25 | c.180G>A p.E60= | Silent (SNP) | VAF 34/120 reads (28%) | called by muse, mutect2, varscan2
- CPSF3 | c.250C>T p.L84= | Silent (SNP) | VAF 35/100 reads (35%) | called by muse, mutect2, varscan2
- FARSB | c.492G>A p.L164= | Silent (SNP) | VAF 72/182 reads (40%) | called by muse, mutect2, varscan2
- IGHV2-70D | c.219T>C p.D73= | Silent (SNP) | VAF 58/119 reads (49%) | called by muse, varscan2
- KDM4B | c.1401G>A p.P467= | Silent (SNP) | VAF 65/93 reads (70%) | catalogued as rs752921694; called by muse, mutect2, varscan2
- KIAA0586 | c.249G>T p.V83= (on ENST00000619416 / NM_001244190.2; = p.V98= on NM_014749.5) | Silent (SNP) | VAF 17/51 reads (33%) | called by muse, mutect2, varscan2
- KIRREL3 | c.2049C>T p.S683= | Silent (SNP) | VAF 43/175 reads (25%) | catalogued as rs370077884; called by muse, mutect2, varscan2
- MYH11 | c.690C>T p.N230= | Silent (SNP) | VAF 34/88 reads (39%) | catalogued as rs561105158; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCDHA12 | c.1629G>A p.P543= | Silent (SNP) | VAF 28/93 reads (30%) | catalogued as rs375706181; called by muse, mutect2, varscan2
- PKP3 | c.63G>A p.A21= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs988491372; called by muse, mutect2, varscan2
- SH3RF3 | c.88C>A p.R30= | Silent (SNP) | VAF 26/42 reads (62%) | called by muse, mutect2, varscan2
- SLITRK4 | c.2070T>A p.T690= | Silent (SNP) | VAF 95/315 reads (30%) | called by muse, mutect2, varscan2
- AC016868.1 | n.313A>T | RNA (SNP) | VAF 9/198 reads (5%) | called by muse, mutect2
- ACER3 | c.*4705A>G | 3'UTR (SNP) | VAF 20/41 reads (49%) | called by muse, mutect2, varscan2
- ADGRL2 | c.3102-11T>G | Intron (SNP) | VAF 65/123 reads (53%) | called by muse, mutect2, varscan2
- AGAP1 | c.*1533G>T | 3'UTR (SNP) | VAF 17/53 reads (32%) | called by muse, mutect2, varscan2
- ARC | c.*360C>T | 3'UTR (SNP) | VAF 5/72 reads (7%) | catalogued as rs1057025340; called by muse, mutect2
- BCL10 | c.-232C>T | 5'UTR (SNP) | VAF 50/104 reads (48%) | catalogued as rs747132908; called by muse, mutect2, varscan2
- C2orf72 | c.*889C>T | 3'UTR (SNP) | VAF 46/116 reads (40%) | called by muse, mutect2, varscan2
- CAAP1 | c.*101G>T | 3'UTR (SNP) | VAF 17/50 reads (34%) | called by muse, mutect2, varscan2
- CDRT15P2 | n.80G>A | RNA (SNP) | VAF 6/16 reads (38%) | catalogued as rs566544432; called by muse, varscan2
- CERCAM | chr9:128420842 G>C | 5'Flank (SNP) | VAF 13/63 reads (21%) | called by muse, mutect2, varscan2
- CGREF1 | chr2:27100993 C>A | 3'Flank (SNP) | VAF 33/77 reads (43%) | called by muse, mutect2, varscan2
- COG8 | c.377+23G>A | Intron (SNP) | VAF 26/138 reads (19%) | called by muse, mutect2, varscan2
- CTSL | c.127-119A>G | Intron (SNP) | VAF 26/90 reads (29%) | called by muse, mutect2, varscan2
- EIF3B | c.1687+29G>T | Intron (SNP) | VAF 68/271 reads (25%) | catalogued as rs756902192; called by muse, mutect2, varscan2
- FER | c.*1536T>C | 3'UTR (SNP) | VAF 31/112 reads (28%) | called by muse, mutect2, varscan2
- GOLT1B | c.*62T>A | 3'UTR (SNP) | VAF 8/91 reads (9%) | called by muse, mutect2
- HAUS6P3 | n.780A>C | RNA (SNP) | VAF 85/279 reads (30%) | called by muse, mutect2, varscan2
- IKBKB | c.105+12G>A | Intron (SNP) | VAF 70/156 reads (45%) | catalogued as COSV60595538; called by muse, mutect2, varscan2
- KLHL21 | c.*1534G>A | 3'UTR (SNP) | VAF 14/102 reads (14%) | called by muse, mutect2, varscan2
- LINC00840 | n.60C>A | RNA (SNP) | VAF 46/91 reads (51%) | called by muse, mutect2, varscan2
- MCMBP | c.*1232C>T | 3'UTR (SNP) | VAF 25/74 reads (34%) | called by muse, mutect2, varscan2
- MIPOL1 | c.*1438T>A | 3'UTR (SNP) | VAF 39/69 reads (57%) | called by muse, mutect2, varscan2
- MYO10 | c.*274G>A | 3'UTR (SNP) | VAF 34/137 reads (25%) | called by muse, mutect2, varscan2
- NCOA4 | c.-15+3019C>T | Intron (SNP) | VAF 23/142 reads (16%) | called by muse, mutect2, varscan2
- NTRK2 | c.1585+9148G>C | Intron (SNP) | VAF 41/138 reads (30%) | called by muse, mutect2, varscan2
- PIK3R1 | c.1020-152T>A | Intron (SNP) | VAF 14/40 reads (35%) | called by muse, varscan2
- PKD2 | c.-93C>T | 5'UTR (SNP) | VAF 21/50 reads (42%) | catalogued as rs1235606078; called by muse, mutect2, varscan2
- PLBD1 | c.115+29C>G | Intron (SNP) | VAF 4/23 reads (17%) | catalogued as rs1298135585; called by muse, mutect2, varscan2
- PLCXD3 | c.*3878C>T | 3'UTR (SNP) | VAF 32/103 reads (31%) | catalogued as rs753271057; called by muse, mutect2, varscan2
- PLXNB1 | c.3795-72G>A | Intron (SNP) | VAF 33/83 reads (40%) | catalogued as rs1181975776; called by muse, mutect2, varscan2
- PSMC2 | c.-251T>C | 5'UTR (SNP) | VAF 20/68 reads (29%) | called by muse, mutect2, varscan2
- RIMS2 | c.*1202A>C | 3'UTR (SNP) | VAF 29/68 reads (43%) | called by muse, mutect2, varscan2
- ROBO2 | c.3761-2235G>T | Intron (SNP) | VAF 16/48 reads (33%) | called by muse, mutect2, varscan2
- SLC48A1 | chr12:47770908 G>A | 5'Flank (SNP) | VAF 52/125 reads (42%) | catalogued as rs1174476851; called by muse, mutect2, varscan2
- TFAM | c.*994A>T | 3'UTR (SNP) | VAF 3/19 reads (16%) | catalogued as COSV65876585; called by muse, mutect2
- TMEM167B | chr1:109088245 G>T | 5'Flank (SNP) | VAF 25/64 reads (39%) | catalogued as rs1284901851; called by muse, mutect2, varscan2
- TNFRSF25 | c.39+15A>G | Intron (SNP) | VAF 25/46 reads (54%) | called by muse, mutect2, varscan2
- TNIP1 | c.*601C>T | 3'UTR (SNP) | VAF 39/191 reads (20%) | called by muse, mutect2, varscan2
- TOP2B | chr3:25664457 A>C | 5'Flank (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- UGT1A6 | c.862-23180C>A | Intron (SNP) | VAF 40/142 reads (28%) | called by muse, mutect2, varscan2
- ZBTB17 | c.2039-36G>A | Intron (SNP) | VAF 38/97 reads (39%) | catalogued as rs757509755; called by muse, mutect2, varscan2
- ZBTB40 | c.*929T>G | 3'UTR (SNP) | VAF 13/30 reads (43%) | called by muse, mutect2, varscan2
